Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A820, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A820-01A (Primary Tumor).

Date:

Translate on from the original pathology evaluated on

RIGHT ADRENALECTOMY

Macroscopy

The non oriented surgical specimen measures 90x75x60 mm. The mass contains a 5cm cavity with necrotic material.

At periphery of the tumor there is an apparently normal adrenal tissue.

Separately it has been sent a lumbo-aortic lymph node.

Microscopy

The histological aspects are suggestive of pheochromocytoma. The tumor cells have variable size with flue limits, abundant and finely granular cytoplasm, with highly atypical nuclei, nuclear pleomorphisms (PASS 1), and hyperchromasia (PASS 1). To note: the presence of frequent nuclear inclusions and more rare intracytoplasmic hyaline globules. Fusiformis cells are also present (PASS 2). The mitoses are rare (3 mitoses/ 10 HPF) (PASS 0), but atypical (PASS 2).

Tumor cells are sometimes arranged in large nests (PASS 2), separated by a finely vascular stroma. Many hemorrhagic alterations are observed in this tumor. The tumor invades in several points the surrounding adrenal cortex without exceeding it. To note: the presence of vascular lymphatic invasion (PASS 1).

A PASS score of 9 suggests a malignant pheochromocytoma.

The lumbo-aortic lymph node is normal.

Conclusions

Right adrenal pheochromocytoma with a PASS score of 9 suggestive of malignancy.

The lumbo-aortic lymph node is normal.

ICD-O-3
Pheochromocytoma NOS
8700/3
Site Adrenal gland NOS
C74.9
JW 10/17/13

Source: NCI Genomic Data Commons file a721a127-118d-4def-9350-69a63a464126 (TCGA-WB-A820.AA960B9F-A4F9-48BE-8420-22BEEA7CA990.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).